Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7X1, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7X1-01A (Primary Tumor).

Gross:

Left adrenal with tumor (weight 60g, 80x50x35 mm). Tumor consists from two thinly adjacent and probably related nodules, smaller 25x35x20 mm, larger 60x40x40 mm. On cut, both are grey-pink and soft. In the center of the larger nodule, yellow focus probably scarification.

Smaller nodule was processed in representative cross-section with the largest diameter in 1 block (1A), larger nodule similarly (1B-1E).

Micro:

In excisions from both nodules were found similar structures of alveolarly shaped pheochromocytoma with large regressive changes in the center of the larger nodule. On the periphery of tumor excisions, adrenal cortex remnants with pressure atrophy, somewhere with extracapsular proliferates. No pheochromocytoma infiltration in the periadrenal tissue was found in the examined excisions.

Imunohistochemic examination:

S100 protein – slightly variable density, but clear presence of sustentacular cells

MIB-1 < 1% tumor nuclei

PASS:

Large nests or diffuse growth (>10% of tumor volume)

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 2

Procurement date:

Confirmation date:

IAD 0-3
Pheochromocytoma NOS
8700/0
Site @ Adrenal gland
C74.9
gt 10/10/13

Source: NCI Genomic Data Commons file f6372a21-a777-4b58-83d4-cf98d6cdf4f0 (TCGA-S7-A7X1.909E3416-1004-41DE-B5E9-5646EDE1E148.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).